Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98G, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98G-01A (Primary Tumor).

[page 1 of 3]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

ICD-O-3
Mesothelioma, biphasic
malignant 9053/3
Site R Pleura NOS C38.4
9/23/12/14

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. #11 lymph node; biopsy:

- Two lymph nodes, no tumor (0/2).

B. Level 7 lymph node; dissection:

- Three lymph nodes, no tumor (0/3).

C. #8 lymph node; biopsy:

- One lymph node, no tumor (0/1).

D. 4R lymph node; biopsy:

- Two lymph nodes, no tumor (0/2).

E. Right parietal and visceral pleura, diaphragm and pericardium:

- Malignant biphasic mesothelioma; see comment.

- See parameters.

Thoracic Mesothelioma Pathologic Parameters

Pleura Resection

MACROSCOPIC

Specimen Type: Pleural resection

Tumor Site: Right pleura, pericardium, and diaphragm

Tumor Configuration and Size: Diffuse, maximum thickness: 3.5 cm

MICROSCOPIC

Histologic Type: Biphasic mesothelioma (80% epithelioid, 20% sarcomatoid)

Tumor Extension:

Confluent visceral pleural tumor (including fissure)

Into but not through diaphragm

Into and through the pericardium

Venous/Lymphatic (Large/Small Vessel) Invasion: Absent

Margins: Cannot be assessed

Pathologic Staging (pTNM): pT4, N0

Primary Tumor (pT)

[page 2 of 3]
pT4: Tumor (locally advanced technically unresectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: diffuse or multifocal invasion of soft tissues of the chest wall, any involvement of rib, invasion through the diaphragm to the peritoneum, invasion of any mediastinal organ(s), direct extension to the contralateral pleura, invasion into the spine, extension to the internal surface of the pericardium, pericardial effusion with positive cytology, invasion of the myocardium.

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Specify: Number examined: 8

Number involved: 0

Comment

Immunohistochemical staining with CAM5.2 was positive in both epithelioid and sarcomatoid mesothelioma. Of note, expansile nodules composed of sarcomatoid mesothelioma are seen at the diaphragm with epithelioid and spindle cells extending into the muscle. In the invasive areas, only the epithelioid cells stain positively for CAM5.2, whereas the spindle cells are negative. This shows epithelioid mesothelioma extension into the diaphragm, but spindle cells within the diaphragm may reflect desmoplastic stroma. In addition, CD34 stain shows no venous or lymphatic invasion. All controls are appropriate. Dr. [] has reviewed the case and concurs.

xxx

[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a []-year-old male with mesothelioma undergoing right thoracotomy, pleurectomy, and decortication.

Specimens Received:

A: #11

B: Level 7

C: #8

D: 4R

E: Right parietal visceral pleura diaphragm and pericardium

Gross Description:

The specimens are received in five containers each labeled with the patient's name and medical record number.

[page 3 of 3]
A. The first container is additionally identified as, "1. #11". Received fresh and placed in formalin are 2 gray-black nodular, rubbery fibrofatty tissue fragments measuring 0.8 x 0.7 x 0.6 cm and 1.2 x 0.7 x 0.6 cm. Each nodule is bisected. A thin section of tissue is detached from the larger nodule during bisection. The smaller nodule is submitted entirely in A1, and the larger nodule along with the detached fragment is submitted in A2.

B. The second container is additionally identified as, "2. Level 7". Received fresh and placed in formalin are 3 grey-black nodular, rubbery fibrofatty tissue fragments measuring 0.8 x 0.4 x 0.3 cm, 1.9 x 1.1 x 0.6 cm, and 1.9 x 1.1 x 0.8 cm. Each nodule is bisected and submitted entirely in B1-B3.

C. The third container is additionally identified as, "3. #8". Received fresh and placed in formalin is a grey-black nodular, rubbery fibrofatty tissue fragment measuring 1.8 x 1.2 x 0.6 cm. The specimen is bisected and submitted entirely in C1.

D. The fourth container is additionally identified as, "4. 4R". Received fresh and placed in formalin are 2 brown-tan rubbery tissue fragments measuring 1.1 x 0.5 x 0.4 cm and 1.5 x 1 x 0.3 cm as well as a gray-black lobulated, rubbery fibrofatty tissue fragment measuring 3.1 x 2.3 x 0.3 cm. The 2 brown-tan fragments are submitted entirely in D1. The gray-black larger tissue fragment is divided and submitted entirely in D2-D3.

E. The fifth container is additionally identified as, "5. Right parietal visceral pleura, diaphragm + pericardium black stitch marks pericardium, white stitch marks diaphragm". Received fresh is a 575 gm, 600 ml pleurectomy specimen measuring 31 x 16 x 3 cm. There is an attached 6.5 x 2.5 cm surface of smooth, pink-tan pericardium, which is 0.2 cm thick. There is a 13 x 11 cm portion of attached red-brown, ragged diaphragm, which is 0.8 cm thick. The specimen is inked as follows: pericardial surface - blue, abdominal surface of diaphragm - black. The specimen is sectioned to reveal white, firm, lobulated tumor present throughout the visceral pleura. Greater than 90% of the pleura is involved by tumor. The visceral and parietal pleura are thickened (up to 0.5 cm) and fused. The tumor invades the diaphragm up to a depth of 0.8 cm, which comes to <0.1 cm to the inked margin. The abdominal surface of the diaphragm is free of tumor. The greatest tumor dimension is 3.5 cm. Gross photographs are taken.

Representative sections are taken as follow:

E1-E2: Pericardium

E3-E9: Diaphragm

E10-E15: Pleura and chest wall

xxx

☐ MD

Source: NCI Genomic Data Commons file b67840d1-b5a0-4d8a-8aea-43168f0e9bfa (TCGA-3U-A98G.7462A92B-C657-4D38-BF7C-0EC9639E7E4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).